Somatic mutation profile of tumor specimen 591fb460-703a-437d-8d9a-ff2a35 (aliquot 591fb460-703a-437d-8d9a-ff2a35_D6) from CPTAC case 11CO043, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen 591fb460-703a-437d-8d9a-ff2a35: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fab846a8-893a-498a-ba9c-fae42aa59cb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 4eb92587-cfca-47b3-8cc9-0d4a64 (Blood Derived Normal), aliquot 4eb92587-cfca-47b3-8cc9-0d4a64_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cbf7c97a-93c0-40c8-96a5-2897dcd04467

The open-access MAF lists 137 somatic variants for this specimen: 94 protein-altering or splice-affecting, 29 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 29, Nonsense Mutation 7, RNA 5, Intron 4, Splice Region 2, 5'Flank 2, 3'UTR 2, Splice Site 2, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 116/235 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SYNE1 | c.24139C>T p.R8047* (on ENST00000367255 / NM_182961.4; = p.R7976* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 61/318 reads (19%) | catalogued as rs1174316105; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 106/211 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- ACTA1 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 24/376 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as CM034495, COSV64204280; called by muse, mutect2
- AOX1 | c.1991C>T p.A664V | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.258); catalogued as rs146370823; called by muse, mutect2, varscan2
- CEP295 | c.7583G>A p.R2528H | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs1017332956; called by muse, mutect2, varscan2
- CFAP43 | c.1343C>T p.T448M | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs538157333; called by muse, mutect2, varscan2
- CFAP58 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as rs368633237; called by muse, varscan2
- CGB5 | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 47/384 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.096); catalogued as rs549743822; called by muse, mutect2, varscan2
- CGB8 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 137/440 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.086); catalogued as rs1386494839; called by muse, mutect2, varscan2
- COL11A1 | c.5030G>A p.R1677K | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.476); catalogued as COSV62200594; called by muse, mutect2, varscan2
- CTNNA2 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751827909, COSV63554385; called by muse, mutect2, varscan2
- CYP26A1 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV56418606; called by muse, mutect2, varscan2
- ELMO2 | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs894701375; called by muse, mutect2, varscan2
- FAM135B | c.2408G>C p.S803T | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV52716667, COSV52755853; called by muse, mutect2
- GPR32 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 82/229 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs778498523, COSV54514344; called by muse, mutect2, varscan2
- GRIA2 | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 120/252 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV52402787; called by muse, mutect2, varscan2
- GRIP2 | c.3160G>A p.V1054I (on ENST00000619221; = p.V957I on NM_001080423.4) | Missense Mutation (SNP) | VAF 81/132 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.069); catalogued as rs761275128; called by muse, mutect2, varscan2
- HDGFL2 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1277582666, COSV56682733; called by muse, mutect2, varscan2
- HMMR | c.1588A>G p.T530A | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs1484019171; called by muse, mutect2, varscan2
- KCNJ5 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 151/568 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs139073333; ClinVar: likely benign; called by muse, mutect2, varscan2
- KYNU | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.417); catalogued as rs545230086, COSV51591996; called by muse, mutect2, varscan2
- MAPKBP1 | c.3371C>T p.S1124L (on ENST00000456763 / NM_001128608.2; = p.S1118L on NM_014994.3) | Missense Mutation (SNP) | VAF 54/240 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs142103818; called by muse, mutect2, varscan2
- MEGF8 | c.6706G>A p.D2236N (on ENST00000251268 / NM_001271938.2; = p.D2169N on NM_001410.3) | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.018); catalogued as rs747093369; called by muse, mutect2, varscan2
- MTCL1 | c.3752G>A p.R1251H (on ENST00000306329 / NM_001378206.1; = p.R932H on NM_015210.4) | Missense Mutation (SNP) | VAF 110/198 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.715); catalogued as rs765671835; called by mutect2, varscan2
- NELFA | c.1094G>A p.R365H (on ENST00000542778; = p.R354H on NM_005663.5) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); catalogued as rs748816112; called by muse, mutect2, varscan2
- NLRP12 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 39/307 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs141779249; called by muse, mutect2, varscan2
- NLRP2 | c.399G>A p.A133= | Splice Region (SNP) | VAF 41/99 reads (41%) | catalogued as rs145145515, COSV54759855; called by muse, varscan2
- NRF1 | c.1318G>A p.G440R | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs368702964, COSV56217093; called by mutect2, varscan2
- OBSCN | c.7222C>T p.R2408W | Missense Mutation (SNP) | VAF 106/347 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs775749451, COSV52747557; called by muse, mutect2, varscan2
- OCA2 | c.493C>T p.R165* | Nonsense Mutation (SNP) | VAF 63/292 reads (22%) | catalogued as CM1414782; called by muse, mutect2, varscan2
- PCDHA1 | c.2075C>T p.A692V | Missense Mutation (SNP) | VAF 24/586 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV65372722; called by muse, mutect2
- PHLDB1 | c.3667A>T p.T1223S | Missense Mutation (SNP) | VAF 97/243 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.621); catalogued as COSV100616450; called by muse, mutect2, varscan2
- PIGR | c.2278G>A p.G760S | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs199922959; called by muse, mutect2, varscan2
- PLA2G4A | c.1114T>C p.F372L | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs970940557; called by muse, mutect2
- PLPPR4 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.195); catalogued as rs201281186, COSV64564801; called by muse, mutect2, varscan2
- PTPRS | c.2624C>T p.S875L | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV99512050; called by muse, mutect2, varscan2
- RIMBP2 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs745629723; called by muse, mutect2, varscan2
- SDK1 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 61/168 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1289665015, COSV67360865; called by muse, mutect2, varscan2
- SEL1L2 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs373425656; called by muse, mutect2, varscan2
- SLC10A2 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 145/448 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as rs147515410; called by muse, varscan2
- SLC10A2 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 114/322 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs148415870, COSV55359465; called by muse, varscan2
- SNED1 | c.708G>A p.M236I | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs1472606729; called by muse, mutect2, varscan2
- TBX21 | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 44/250 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs752687196, COSV99456264; called by muse, varscan2
- TCF7L2 | c.1219C>T p.R407* (on ENST00000355995 / NM_001367943.1; = p.R384* on NM_030756.5) | Nonsense Mutation (SNP) | VAF 37/116 reads (32%) | catalogued as COSV53338146; called by muse, mutect2, varscan2
- TRAV19 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 51/226 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769530808; called by muse, mutect2, varscan2
- TRIM51 | c.1189C>T p.L397F | Missense Mutation (SNP) | VAF 218/557 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV99792514; called by muse, mutect2, varscan2
- TTN | c.43576C>T p.R14526* (on ENST00000591111; = p.R7102* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 28/175 reads (16%) | catalogued as rs1312425985, COSV59984379, COSV60032660; called by muse, mutect2, varscan2
- UNC93B1 | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs766109609; called by muse, mutect2, varscan2
- VAV1 | c.1141C>T p.R381* | Nonsense Mutation (SNP) | VAF 28/246 reads (11%) | catalogued as COSV58388645; called by muse, mutect2, varscan2
- WIF1 | c.922+1G>A p.X308_splice | Splice Site (SNP) | VAF 27/62 reads (44%) | catalogued as rs1385882260, COSV54137285; called by muse, mutect2, varscan2
- ZFHX4 | c.857C>A p.S286Y | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50509714; called by muse, mutect2
- ZNF43 | c.1109A>G p.Y370C | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); catalogued as rs1393374199; called by muse, mutect2
- ZNF658 | c.2282G>A p.R761Q | Missense Mutation (SNP) | VAF 37/252 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201576684; called by mutect2, varscan2
- ZNF831 | c.1186G>A p.G396S | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100925684; called by muse, mutect2, varscan2
- ABCA13 | c.12126C>A p.D4042E | Missense Mutation (SNP) | VAF 26/304 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2
- ACTL6B | c.357G>T p.M119I | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- BTRC | c.655A>G p.T219A (on ENST00000370187 / NM_033637.4; = p.T183A on NM_003939.5) | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CARM1 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 14/79 reads (18%) | called by muse, mutect2, varscan2
- CSMD3 | c.3022T>C p.Y1008H (on ENST00000297405 / NM_001363185.1; = p.Y904H on NM_052900.3) | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.013); called by mutect2, varscan2
- DNAH12 | c.437G>C p.S146T | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2
- ELMO1 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FER1L5 | c.2897dup p.E968Rfs*8 (on ENST00000623019; = p.E975Rfs*8 on NM_001293083.2) | Frame Shift Ins (INS) | VAF 18/66 reads (27%) | called by mutect2, pindel, varscan2
- FRMPD3 | c.418A>G p.S140G | Missense Mutation (SNP) | VAF 66/145 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- FTL | c.347C>A p.A116D | Missense Mutation (SNP) | VAF 186/440 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- GFUS | c.898C>A p.P300T | Missense Mutation (SNP) | VAF 40/280 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- H3C7 | c.337A>G p.I113V | Missense Mutation (SNP) | VAF 49/250 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- KCNRG | c.793C>G p.P265A | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KDM4C | c.2290G>T p.A764S | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMA4 | c.3694C>T p.L1232F (on ENST00000230538 / NM_001105206.3; = p.L1225F on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/318 reads (25%) | SIFT tolerated (0.39); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRGUK | c.2170C>A p.P724T | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- LRRD1 | c.2491C>G p.Q831E | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.138); called by muse, mutect2
- MAGEB16 | c.499G>T p.G167C | Missense Mutation (SNP) | VAF 37/413 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAP3K15 | c.586T>G p.C196G | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- MAP4K4 | c.254A>G p.Y85C | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCF2 | c.1243G>A p.G415S | Missense Mutation (SNP) | VAF 130/450 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); called by mutect2, varscan2
- OR4S2 | c.754T>A p.C252S | Missense Mutation (SNP) | VAF 72/237 reads (30%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHGDH | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 35/242 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PI4K2A | c.590G>T p.S197I | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- POLA1 | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 8/76 reads (11%) | called by mutect2, varscan2
- RPUSD3 | c.266C>A p.P89H | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.492); called by mutect2, varscan2
- SERPINF2 | c.41G>T p.C14F | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- SLC39A5 | c.329T>C p.M110T | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SLITRK2 | c.547C>A p.L183M | Missense Mutation (SNP) | VAF 28/354 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- STPG4 | c.13G>C p.A5P | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- TBC1D3I | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 45/379 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TBC1D8 | c.3337G>C p.E1113Q | Missense Mutation (SNP) | VAF 42/261 reads (16%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- TSTD2 | c.292A>C p.T98P | Missense Mutation (SNP) | VAF 108/204 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- TTK | c.851G>A p.C284Y | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBR3 | c.1779G>A p.R593= | Splice Region (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2, varscan2
- VPS13D | c.5344G>T p.D1782Y | Missense Mutation (SNP) | VAF 83/182 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- YJEFN3 | c.318+2T>C p.X106_splice | Splice Site (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- ZDBF2 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ZNF675 | c.1087A>G p.T363A | Missense Mutation (SNP) | VAF 67/284 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- ADAMTS2 | c.1419C>T p.H473= | Silent (SNP) | VAF 94/260 reads (36%) | catalogued as rs758260638, COSV51088534; called by muse, mutect2, varscan2
- AHNAK2 | c.285A>G p.S95= | Silent (SNP) | VAF 65/173 reads (38%) | called by muse, mutect2, varscan2
- AMOTL1 | c.1485G>A p.S495= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as rs763554888; called by muse, mutect2, varscan2
- BRWD1 | c.1596C>G p.A532= | Silent (SNP) | VAF 25/61 reads (41%) | called by muse, mutect2, varscan2
- C11orf96 | c.108C>T p.G36= | Silent (SNP) | VAF 101/208 reads (49%) | called by muse, mutect2, varscan2
- CCM2L | c.153C>T p.I51= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as COSV52949907; called by muse, mutect2, varscan2
- CEMIP | c.3438C>T p.N1146= | Silent (SNP) | VAF 67/373 reads (18%) | catalogued as rs537667306, COSV99585809; called by muse, mutect2, varscan2
- COG3 | c.1149T>A p.L383= | Silent (SNP) | VAF 31/79 reads (39%) | called by muse, mutect2, varscan2
- DOHH | c.663G>A p.A221= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs1371839598; called by muse, mutect2, varscan2
- DYNC2I2 | c.267G>A p.T89= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as rs137886760, COSV65548969; called by muse, mutect2, varscan2
- ERI3 | c.342G>A p.E114= | Silent (SNP) | VAF 37/116 reads (32%) | catalogued as COSV64832168; called by muse, mutect2, varscan2
- GAGE2E | c.321G>A p.T107= | Silent (SNP) | VAF 37/1057 reads (4%) | called by muse, mutect2
- GDF6 | c.612G>A p.P204= | Silent (SNP) | VAF 49/188 reads (26%) | called by muse, mutect2, varscan2
- GHRHR | c.378C>T p.F126= | Silent (SNP) | VAF 42/363 reads (12%) | called by muse, mutect2, varscan2
- GNB1L | c.681C>T p.S227= | Silent (SNP) | VAF 143/234 reads (61%) | catalogued as rs376426350; called by muse, mutect2, varscan2
- GRIA2 | c.2523C>T p.A841= | Silent (SNP) | VAF 25/163 reads (15%) | catalogued as rs759531543, COSV52408970; called by muse, mutect2, varscan2
- GTF2F1 | c.609C>T p.S203= | Silent (SNP) | VAF 32/239 reads (13%) | catalogued as rs34220695; called by muse, mutect2, varscan2
- HAUS7 | c.802C>T p.L268= | Silent (SNP) | VAF 183/519 reads (35%) | called by mutect2, varscan2
- KCNH4 | c.1881G>A p.G627= | Silent (SNP) | VAF 106/317 reads (33%) | called by muse, varscan2
- LHX5 | c.1038G>A p.S346= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as rs1203074018; called by muse, mutect2, varscan2
- MMP23B | c.648G>A p.A216= | Silent (SNP) | VAF 6/47 reads (13%) | called by mutect2, varscan2
- NOTCH1 | c.387C>T p.C129= | Silent (SNP) | VAF 15/434 reads (3%) | catalogued as COSV53051441; called by muse, mutect2
- PCDHB6 | c.1335C>T p.N445= | Silent (SNP) | VAF 20/436 reads (5%) | catalogued as rs1554277740, COSV50689781; called by muse, mutect2
- SERPINB13 | c.918C>T p.G306= | Silent (SNP) | VAF 62/120 reads (52%) | catalogued as rs761827636; called by muse, mutect2, varscan2
- STRA8 | c.534C>T p.S178= (on ENST00000275764; = p.S156= on NM_182489.2) | Silent (SNP) | VAF 35/454 reads (8%) | called by muse, mutect2
- TECTA | c.4629G>A p.S1543= | Silent (SNP) | VAF 171/425 reads (40%) | catalogued as rs1299643847, COSV50755173; called by muse, mutect2, varscan2
- TFAP2B | c.840G>A p.G280= | Silent (SNP) | VAF 76/338 reads (22%) | called by muse, mutect2, varscan2
- TGIF2LX | c.687C>T p.A229= | Silent (SNP) | VAF 21/190 reads (11%) | catalogued as rs763936281; called by muse, mutect2, varscan2
- XPO1 | c.2701T>C p.L901= | Silent (SNP) | VAF 16/122 reads (13%) | called by muse, mutect2, varscan2
- AC099654.5 | n.44C>A | RNA (SNP) | VAF 14/53 reads (26%) | catalogued as rs1235817769; called by muse, mutect2, varscan2
- ATP8A2 | c.2211+1584C>T | Intron (SNP) | VAF 10/164 reads (6%) | called by muse, mutect2
- DNM1P46 | n.609G>A | RNA (SNP) | VAF 57/534 reads (11%) | catalogued as rs532901507; called by muse, varscan2
- FAM90A27P | n.827C>G | RNA (SNP) | VAF 73/202 reads (36%) | called by muse, mutect2, varscan2
- FAS | c.*1647G>A | 3'UTR (SNP) | VAF 12/58 reads (21%) | catalogued as rs192544176; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FGR | c.226+71G>A | Intron (SNP) | VAF 65/177 reads (37%) | catalogued as rs371971160; called by muse, mutect2, varscan2
- MORC2 | c.*5A>T | 3'UTR (SNP) | VAF 8/70 reads (11%) | called by muse, varscan2
- PLEKHH1 | c.3933+281A>C | Intron (SNP) | VAF 22/104 reads (21%) | called by muse, mutect2, varscan2
- RGPD1 | c.48+5896G>A | Intron (SNP) | VAF 18/94 reads (19%) | catalogued as COSV101233567; called by muse, mutect2, varscan2
- SDHAP1 | n.1184G>A | RNA (SNP) | VAF 47/229 reads (21%) | catalogued as rs1413242411; called by muse, mutect2, varscan2
- SDHAP2 | n.1062G>A | RNA (SNP) | VAF 57/142 reads (40%) | called by muse, mutect2, varscan2
- TRIM74 | chr7:72969755 G>A | 5'Flank (SNP) | VAF 32/432 reads (7%) | catalogued as rs1371922075; called by muse, mutect2
- USP12 | c.-75G>A | 5'UTR (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- WT1 | chr11:32439269 G>A | 5'Flank (SNP) | VAF 52/407 reads (13%) | called by muse, mutect2, varscan2
